MMRF case MMRF_1690 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1365c987-1c56-474e-ab2b-7f53cabf3cb0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.8 years (21,110 days); ISS stage: I; Days to last known disease status: 1,150 days (3.1 years); Days to last follow up: 1,150 days (3.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 139 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 345 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 345 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 345 days; Days to treatment end: 625 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 345 days; Days to treatment end: 401 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 345 days; Days to treatment end: 653 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 401 days (1.1 years); Days to treatment end: 457 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 401 days (1.1 years); Days to treatment end: 569 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 457 days (1.3 years); Days to treatment end: 569 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 569 days (1.6 years); Days to treatment end: 625 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 653 days (1.8 years); Days to treatment end: 734 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 734 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 12.8 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 6.44 mmol/L; C-Reactive Protein 3.3 mg/dL.
- Day 86 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.539 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.09 mg/dL; Immunoglobulin G 3.58 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 4.65 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.72 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.
- Day 165 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.953 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.15 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.91 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.16 mmol/L.
- Day 254 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.132 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 345 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.647 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.824 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.94 mmol/L.
- Day 457 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.225 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 513 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.191 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 4.3 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 625 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.132 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 716 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.823 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 800 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.871 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.891 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 884 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 996 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.54 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 1,087 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.953 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 9.32 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 1,150 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 1.47 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 7.1 mmol/L.

Other clinical attributes
- Day -17: Weight: 70 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1690_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1690_3_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
